Gene-level copy-number profile of tumor specimen TCGA-LN-A4MQ-01A from TCGA case TCGA-LN-A4MQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 46.5 years (16,990 days).
Specimen TCGA-LN-A4MQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.b3e0034d-6fee-4abb-a9cb-36b3a8289010.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A4MQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/12d4f7db-3c94-4a10-ac24-a4e3b4fb2402

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 514; copy number 2: 13,923; copy number 3: 18,410; copy number 4: 15,729; copy number 5: 7,188; copy number 6: 1,541; copy number 7: 811; copy number 8: 366; copy number 9: 438; copy number 10: 816; copy number 11: 39; copy number 12: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A4MQ-01A-11D-A28A-01): tumor purity 0.64, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,504 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:119,759,922–121,809,962, 39 genes, copy number 11: PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 7–10 (within-gene range 2–10) (broad region; genes not listed).
- chr5:29,070,496–45,895,970, 271 genes, copy number 8 (broad region; genes not listed).
- chr9:34,179,005–43,045,120, 300 genes, copy number 7–12 (broad region; genes not listed).
- chr18:20,946,906–25,056,760, 94 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 514. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
